Somatic mutation profile of tumor specimen TCGA-HT-A618-01A (aliquot TCGA-HT-A618-01A-11D-A29Q-08) from TCGA case TCGA-HT-A618, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 37.2 years (13,595 days).
Specimen TCGA-HT-A618-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dc45ba8-5179-4142-92d1-babebe44b8c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A618-10A (Blood Derived Normal), aliquot TCGA-HT-A618-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc06a7ec-48c5-433d-88e4-95146b440193

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 11, Silent 7, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 44/58 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.5440G>T p.E1814* | Nonsense Mutation (SNP) | VAF 33/206 reads (16%) | catalogued as COSV64674236, COSV64677946; called by muse, mutect2, varscan2
- ABCA4 | c.5439G>T p.L1813F | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64674241, COSV64675305; called by muse, mutect2, varscan2
- APLNR | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV57242964, COSV99951266; called by muse, mutect2
- APOB | c.11272G>T p.V3758F | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs781117588, COSV51938727; called by muse, mutect2, varscan2
- FLG | c.5282G>A p.R1761H | Missense Mutation (SNP) | VAF 37/454 reads (8%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.976); catalogued as rs375545359, COSV64238304, COSV64253285; called by muse, mutect2
- KCNQ3 | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66472674; called by muse, mutect2
- OR2M2 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62898543; called by muse, mutect2
- OR5M11 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV73141860; called by muse, mutect2, varscan2
- PCNX1 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV53095908; called by muse, mutect2, varscan2
- PI15 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs200713288, COSV52640149, COSV52643049; called by muse, mutect2
- POLN | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV59051477; called by muse, mutect2, varscan2
- SH3BP2 | c.1446T>A p.D482E | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV62554423; called by muse, mutect2
- USP35 | c.1962dup p.T655Hfs*74 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs764735138; called by mutect2, varscan2
- USP44 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as rs1474141572, COSV51564610; called by muse, mutect2, varscan2
- ATRX | c.1361del p.K454Rfs*16 | Frame Shift Del (DEL) | VAF 90/207 reads (43%) | called by mutect2, pindel, varscan2
- ELP6 | c.18_29del p.N7_N10del | In Frame Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel
- LRIT2 | c.149dup p.G51Wfs*5 | Frame Shift Ins (INS) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- CEP164 | c.2076A>G p.Q692= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as COSV99633888; called by mutect2, varscan2
- MED13L | c.861C>A p.I287= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs61756230, COSV99929503; called by muse, varscan2
- OR2T4 | c.426A>G p.S142= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as rs201411128, COSV63543867; called by muse, mutect2
- PCLO | c.6984C>T p.A2328= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs374838410; called by muse, mutect2, varscan2
- RFX2 | c.879G>A p.Q293= | Silent (SNP) | VAF 35/196 reads (18%) | catalogued as COSV57942132; called by muse, mutect2, varscan2
- SIPA1 | c.468G>A p.S156= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as rs371357622, COSV63137439; called by muse, mutect2, varscan2
- THSD4 | c.2346G>A p.P782= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs756282682, COSV55972391; called by muse, mutect2, varscan2
